Somatic mutation profile of cancer-model specimen HCM-BROD-0020-C15-85A (2D Modified Conditionally Reprogrammed Cells, passage 11; aliquot HCM-BROD-0020-C15-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0020-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 67.6 years (24,696 days).
Specimen HCM-BROD-0020-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbee567a-cdbb-4c47-b0eb-1cb88d95f33c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0020-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0020-C15-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea54db36-5095-41d2-bd41-1bcf4202dcfa

The open-access MAF lists 390 somatic variants for this specimen: 285 protein-altering or splice-affecting, 93 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 93, Frame Shift Del 13, Nonsense Mutation 10, Intron 8, Frame Shift Ins 4, Splice Site 2, Splice Region 2, In Frame Ins 2, Nonstop Mutation 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2491_2494del p.L831Ifs*82 | Frame Shift Del (DEL) | VAF 123/452 reads (27%) | catalogued as rs587777522; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDKN2A | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 192/336 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.264); catalogued as rs45476696, CM1414341, CM156717, CS108038, CS972842, COSV58690140, COSV58729212; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYP17A1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894138, CM003806; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 6014/6386 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 131/752 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 241/241 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTR10 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV99581073; called by muse, mutect2, varscan2
- ACTRT1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 172/591 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2, varscan2
- ADPRH | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 208/341 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs528878906, COSV63695715; called by muse, mutect2, varscan2
- AMY1C | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 65/443 reads (15%) | catalogued as rs752371105, COSV64406893; called by muse, mutect2, varscan2
- AMZ1 | c.854T>A p.L285Q | Missense Mutation (SNP) | VAF 182/954 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs759678739; called by muse, mutect2, varscan2
- ANAPC2 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 191/1974 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs761567124; called by muse, mutect2
- AP3B2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 84/773 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1234049432, COSV99917108; called by muse, mutect2, varscan2
- ATP10A | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 152/491 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as rs1288765192, COSV100791095; called by muse, varscan2
- AUP1 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV51206920; called by muse, mutect2, varscan2
- B4GALNT4 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 213/408 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs1214983642, COSV57321564; called by muse, mutect2, varscan2
- C11orf1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs151235350, COSV99500205; called by muse, mutect2
- C21orf62 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs760481485; called by muse, mutect2, varscan2
- C6orf118 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 140/450 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV57814622, COSV57817760; called by muse, mutect2, varscan2
- CA8 | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 235/397 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100527066; called by muse, mutect2, varscan2
- CAPN10 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99550160; called by muse, mutect2, varscan2
- CASR | c.2681G>T p.G894V (on ENST00000490131; = p.G971V on NM_000388.4) | Missense Mutation (SNP) | VAF 160/478 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1270983908; called by mutect2, varscan2
- CDH11 | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 188/394 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV51759327, COSV51759358, COSV51764779; called by muse, varscan2
- CDH22 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 365/739 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs149967017; called by muse, mutect2, varscan2
- CDK14 | c.826G>A p.G276S (on ENST00000380050 / NM_001287135.2; = p.G258S on NM_012395.3) | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756057096, COSV56049976, COSV56057033; called by muse, mutect2, varscan2
- CDKN2A | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 197/431 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58685390, COSV58696112, COSV58702833, COSV58725016; called by muse, mutect2, varscan2
- CEP152 | c.2324C>G p.S775C | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1306429371; called by muse, mutect2, varscan2
- COL6A2 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 166/579 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs754625010; called by muse, mutect2, varscan2
- CPNE5 | c.183G>A p.E61= | Splice Region (SNP) | VAF 112/279 reads (40%) | catalogued as rs780380455, COSV55194346; called by muse, mutect2, varscan2
- CSMD1 | c.6565T>G p.F2189V (on ENST00000520002; = p.F2188V on NM_033225.6) | Missense Mutation (SNP) | VAF 109/355 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59289644; called by muse, mutect2, varscan2
- CYP26C1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 221/406 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1478689286; called by muse, varscan2
- DACH2 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 97/343 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64173392, COSV64179776; called by muse, mutect2, varscan2
- DCAF4L2 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 174/176 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs767512236, COSV60477000; called by muse, mutect2, varscan2
- DDI1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 190/544 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs766051930, COSV56384748; called by muse, mutect2, varscan2
- DGKI | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV55980045; called by muse, mutect2, varscan2
- DHDH | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs543413361; called by mutect2, varscan2
- DNAH12 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 76/199 reads (38%) | catalogued as COSV61061954; called by muse, mutect2, varscan2
- DNMT3A | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 257/467 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs770568549, COSV53057587; called by muse, mutect2, varscan2
- DYSF | c.4304C>T p.A1435V | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs754979997, COSV50326468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EML1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201185419, COSV51743152; called by muse, mutect2, varscan2
- EPHA5 | c.2500A>C p.T834P | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99901215; called by muse, mutect2
- ERBB4 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 270/386 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV99629213; called by muse, mutect2, varscan2
- EXOC6B | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs1317040114, COSV99724450; called by mutect2, varscan2
- FAM189B | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 207/661 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs141156411, COSV100516531; called by muse, mutect2, varscan2
- FARP2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372818608, COSV99883904; called by muse, mutect2, varscan2
- FAT1 | c.12808C>T p.R4270* | Nonsense Mutation (SNP) | VAF 123/344 reads (36%) | catalogued as rs373689624, CM157665; called by muse, mutect2, varscan2
- FLNC | c.3241G>A p.A1081T | Missense Mutation (SNP) | VAF 253/587 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs781760817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN1 | c.2149C>A p.P717T | Missense Mutation (SNP) | VAF 143/233 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1022716034, COSV60561785; called by muse, mutect2, varscan2
- GABRA1 | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 133/299 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50098437; called by muse, mutect2, varscan2
- GRM3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 150/837 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100862178, COSV64469260; called by muse, mutect2, varscan2
- GRM8 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs775957882; called by muse, mutect2, varscan2
- HAAO | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 254/313 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775376402; called by muse, mutect2, varscan2
- HEYL | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 181/362 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.09); catalogued as rs762466594, COSV65722132; called by muse, mutect2, varscan2
- IKBKB | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 98/153 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60595740; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.831dup p.L278Afs*57 (on ENST00000485419 / NM_001197113.1; = p.L202Afs*57 on NM_014575.3) | Frame Shift Ins (INS) | VAF 204/660 reads (31%) | catalogued as rs1553781873; called by mutect2, pindel, varscan2
- ISX | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100434000, COSV58088631; called by muse, mutect2, varscan2
- ITGA5 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 410/410 reads (100%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.793); catalogued as rs377645220; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KIAA1549 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 201/468 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs765692579, COSV54310849; called by muse, varscan2
- KNG1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 57/297 reads (19%) | catalogued as COSV53976096; called by mutect2, varscan2
- LILRA6 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 149/1147 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs781412842, COSV54439906, COSV99558804; called by muse, mutect2, varscan2
- LRIG2 | c.1954C>G p.H652D | Missense Mutation (SNP) | VAF 135/353 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63162452; called by muse, mutect2, varscan2
- MAGEA8 | c.513A>C p.E171D | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99674425, COSV99674717; called by muse, mutect2, varscan2
- MAGEA8 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 165/473 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99674628; called by muse, mutect2, varscan2
- MAGEE1 | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 202/414 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100819199, COSV63910080, COSV63912447; called by muse, mutect2, varscan2
- MAP10 | c.2566T>G p.C856G | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as COSV69365262; called by muse, mutect2, varscan2
- MDFI | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 130/1127 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs374731488; called by muse, mutect2, varscan2
- MGAM | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 123/449 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.52); catalogued as rs1322962933; called by muse, mutect2, varscan2
- MOCS1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182751590; called by muse, mutect2, varscan2
- MUC12 | c.10063G>A p.G3355S (on ENST00000379442; = p.G3212S on NM_001164462.1) | Missense Mutation (SNP) | VAF 374/6880 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs762909547; called by muse, mutect2
- MYCT1 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100924103, COSV65891763; called by muse, mutect2, varscan2
- NETO1 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 144/313 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as rs765206728, COSV55002144, COSV55003500; called by muse, mutect2, varscan2
- NID2 | c.3140G>A p.G1047D | Missense Mutation (SNP) | VAF 149/581 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53495460; called by muse, mutect2, varscan2
- NPY1R | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 108/217 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56713714, COSV56716428; called by muse, mutect2, varscan2
- NT5C3B | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 69/2764 reads (2%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs1166395204; called by muse, mutect2
- NTM | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 124/634 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869147; called by muse, mutect2, varscan2
- NTM | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 124/638 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1329364057, COSV66196004; called by muse, mutect2, varscan2
- NUP205 | c.4426G>A p.A1476T | Missense Mutation (SNP) | VAF 101/449 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.788); catalogued as rs774491809; called by muse, mutect2, varscan2
- OR10J1 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as rs750078681, COSV71128377, COSV71128978; called by muse, mutect2, varscan2
- OR11H1 | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 114/293 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99421930; called by muse, mutect2, varscan2
- OR2T33 | c.189A>C p.Q63H | Missense Mutation (SNP) | VAF 222/708 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV58816941; called by muse, mutect2, varscan2
- OR4F4 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 325/833 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs369935801; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 141/529 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PCDHB6 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 371/371 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554277564, COSV50690487; called by muse, mutect2, varscan2
- PDE1C | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 143/752 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs148832869; called by muse, mutect2, varscan2
- PEG3 | c.1574A>C p.K525T | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV99687457; called by muse, mutect2, varscan2
- PLEKHA4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99612553; called by muse, mutect2, varscan2
- PPM1H | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 135/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205735334, COSV57372660; called by muse, mutect2, varscan2
- PRR33 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 292/668 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1196546517; called by muse, mutect2, varscan2
- RSPO4 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 199/990 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs757714366, COSV99448864; called by muse, varscan2
- SASH1 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 143/435 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as rs1160828003; called by muse, mutect2, varscan2
- SEMA3A | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 95/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750024161, COSV99547008; called by muse, mutect2, varscan2
- SETMAR | c.1806G>T p.L602F | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV62780705; called by muse, mutect2, varscan2
- SLC34A3 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 117/905 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs373242362; called by muse, mutect2, varscan2
- SLCO4C1 | c.1223T>G p.F408C | Missense Mutation (SNP) | VAF 185/275 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60514389; called by muse, mutect2, varscan2
- SMAD2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50998791; called by muse, mutect2, varscan2
- SMARCA4 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 154/297 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1436490540, COSV60807076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.688T>G p.S230A | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100763805; called by muse, mutect2, varscan2
- SPOCD1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1370274935, COSV57096109; called by muse, mutect2, varscan2
- SPTA1 | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs754523316, COSV63750087, COSV63753218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP2 | c.3298T>G p.L1100V | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs558822703; called by muse, mutect2, varscan2
- THEMIS2 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 138/274 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938554585; called by muse, mutect2, varscan2
- TMEM259 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774357289; called by muse, mutect2, varscan2
- TMUB2 | c.724C>T p.R242C (on ENST00000538716 / NM_001353177.2; = p.R222C on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/716 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs775966104; called by muse, mutect2, varscan2
- TNNI3K | c.2200A>G p.S734G | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53946162; called by muse, varscan2
- TTC29 | c.777A>C p.K259N | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57274632; called by muse, mutect2, varscan2
- TTN | c.36650A>G p.N12217S (on ENST00000591111; = p.N4793S on NM_003319.4) | Missense Mutation (SNP) | VAF 106/331 reads (32%) | PolyPhen benign (0.019); catalogued as rs529917511; called by muse, mutect2, varscan2
- USH2A | c.3463A>C p.S1155R | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs766609270, COSV56372284; called by muse, mutect2, varscan2
- USP32 | c.3754G>T p.E1252* | Nonsense Mutation (SNP) | VAF 127/445 reads (29%) | catalogued as COSV100342034; called by muse, mutect2, varscan2
- VWA5B1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 198/457 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374632705, COSV57055123; called by muse, mutect2, varscan2
- WDR87 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs533570505, COSV58204209; called by muse, mutect2, varscan2
- ZFAT | c.2425A>C p.T809P | Missense Mutation (SNP) | VAF 248/1481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100914546; called by muse, mutect2, varscan2
- ZNF208 | c.2325A>C p.K775N | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68111710; called by muse, mutect2, varscan2
- ZNF470 | c.1390C>A p.H464N | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV57967667; called by muse, mutect2
- ZNF521 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 164/273 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.407); catalogued as rs146072050; called by muse, mutect2, varscan2
- ZNF569 | c.449T>A p.F150Y | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57597957; called by muse, mutect2, varscan2
- ZNF587 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 91/614 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs768568016; called by muse, mutect2, varscan2
- ZNF676 | c.381A>C p.K127N (on ENST00000650058; = p.K95N on NM_001001411.3) | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101236395, COSV68092366; called by muse, mutect2, varscan2
- ABCB4 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABI3BP | c.3073C>T p.Q1025* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | called by muse, mutect2, varscan2
- ADAM12 | c.572A>C p.K191T | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ADAMTS16 | c.988A>C p.T330P | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADD2 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AEBP2 | c.136_137insGGG p.E45_E46insG | In Frame Ins (INS) | VAF 283/656 reads (43%) | called by pindel, varscan2
- AEBP2 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 39/968 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); called by muse, mutect2
- AFF3 | c.2258T>G p.L753R | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALLC | c.932T>G p.I311S | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMHR2 | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 86/429 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKRD26 | c.2013G>C p.K671N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.121); called by muse, mutect2
- ANO10 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ARFGEF2 | c.4003G>T p.E1335* | Nonsense Mutation (SNP) | VAF 105/442 reads (24%) | called by muse, mutect2, varscan2
- ARMCX1 | c.1060T>A p.F354I | Missense Mutation (SNP) | VAF 124/384 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATP8B1 | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 155/292 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- AUTS2 | c.1293C>A p.F431L | Missense Mutation (SNP) | VAF 169/860 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.015); called by mutect2, varscan2
- B2M | c.132T>A p.N44K | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BBS9 | c.2270T>C p.L757P (on ENST00000242067 / NM_001348036.1; = p.L717P on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 305/482 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BDH1 | c.933_951del p.Y312Wfs*12 | Frame Shift Del (DEL) | VAF 171/686 reads (25%) | called by mutect2, varscan2
- BDP1 | c.5792del p.V1931Afs*4 | Frame Shift Del (DEL) | VAF 142/286 reads (50%) | called by mutect2, pindel, varscan2
- BIRC6 | c.7211C>T p.A2404V | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRINP1 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BRINP3 | c.1847A>T p.N616I | Missense Mutation (SNP) | VAF 273/409 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- BX276092.9 | c.129T>G p.F43L | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf113 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 29/523 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2
- C8orf76 | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 58/1060 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C9orf131 | c.2663A>G p.E888G | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1A | c.1013T>C p.L338S | Missense Mutation (SNP) | VAF 132/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CACNA1B | c.622A>C p.S208R | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CAND1 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCND1 | c.326_343dup p.V109_K114dup | In Frame Ins (INS) | VAF 96/476 reads (20%) | called by mutect2, varscan2
- CD164L2 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2, varscan2
- CD1E | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDC42BPA | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDK20 | c.580A>G p.M194V (on ENST00000325303 / NM_001039803.3; = p.M173V on NM_012119.4) | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP44 | c.3131C>A p.S1044Y | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- COL15A1 | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CRACR2A | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2
- CRCP | c.240-7_265del p.X80_splice | Splice Site (DEL) | VAF 44/537 reads (8%) | called by mutect2, pindel
- DACH2 | c.1502T>G p.L501R | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DACH2 | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 188/555 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- DCAF5 | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAH5 | c.5563del p.I1855Sfs*16 | Frame Shift Del (DEL) | VAF 373/652 reads (57%) | called by mutect2, pindel, varscan2
- DOCK8 | c.4483T>G p.L1495V | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DOCK8 | c.5251G>T p.V1751F | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- DROSHA | c.1153A>C p.T385P | Missense Mutation (SNP) | VAF 264/575 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1G | c.136A>C p.T46P | Missense Mutation (SNP) | VAF 137/451 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- EFNA2 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- EIF4B | c.1270T>G p.S424A | Missense Mutation (SNP) | VAF 107/388 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ESM1 | c.326T>G p.M109R | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ESPN | c.4054T>G p.W1352G | Missense Mutation (SNP) | VAF 119/228 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- EYS | c.4366A>C p.S1456R | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FAM43B | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 185/363 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FAM90A26 | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 127/213 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FAT4 | c.11440C>A p.Q3814K | Missense Mutation (SNP) | VAF 137/359 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FBXO39 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 129/248 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- FCHSD2 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 96/310 reads (31%) | called by muse, mutect2
- FCHSD2 | c.259T>G p.W87G | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FER1L5 | c.6224C>A p.P2075Q (on ENST00000623019; = p.P2039Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 134/415 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FH | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLT3 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- FREM3 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 84/395 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCLC | c.1153_1156del p.F385Kfs*26 (on ENST00000643939; = p.F383Kfs*26 on NM_001498.4) | Frame Shift Del (DEL) | VAF 86/442 reads (19%) | called by mutect2, pindel, varscan2
- GOLGA8F | c.509A>C p.K170T (on ENST00000526619; = p.K376T on NM_001350920.2) | Missense Mutation (SNP) | VAF 43/907 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2
- GPBAR1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 26/567 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- GPR1 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- GPRIN3 | c.2278T>A p.F760I | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- GSG1L2 | c.515T>G p.L172R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GUCY1A2 | c.1798T>C p.S600P | Missense Mutation (SNP) | VAF 133/344 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCY1B1 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- H4C11 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- HEATR5B | c.2066T>G p.F689C | Missense Mutation (SNP) | VAF 117/228 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- HERC1 | c.9331G>C p.E3111Q | Missense Mutation (SNP) | VAF 140/433 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- HGFAC | c.561C>A p.S187R | Missense Mutation (SNP) | VAF 103/433 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HHLA1 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 111/1506 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- HHLA1 | c.188T>A p.L63H | Missense Mutation (SNP) | VAF 94/1324 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- HK1 | c.2609A>C p.H870P | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- IGLON5 | c.763A>G p.R255G | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- IL13RA2 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1993T>C p.F665L | Missense Mutation (SNP) | VAF 131/388 reads (34%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5D | c.578C>T p.A193V (on ENST00000445964 / NM_001017915.3; = p.A192V on NM_005541.5) | Missense Mutation (SNP) | VAF 269/419 reads (64%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISM2 | c.1358T>C p.F453S | Missense Mutation (SNP) | VAF 48/708 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ITGA2B | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 280/634 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2
- KAT6A | c.2287_2305del p.N763* | Frame Shift Del (DEL) | VAF 132/291 reads (45%) | called by mutect2, pindel, varscan2
- KCNB2 | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 18/443 reads (4%) | SIFT tolerated, low confidence (0.8); PolyPhen possibly damaging (0.659); called by muse, mutect2
- KDM3B | c.2764del p.Y922Tfs*14 | Frame Shift Del (DEL) | VAF 143/528 reads (27%) | called by mutect2, pindel, varscan2
- KIN | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- KRT15 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 204/7219 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LARGE2 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 363/699 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, mutect2
- LARGE2 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 373/700 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2
- LAX1 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 139/401 reads (35%) | called by muse, mutect2, varscan2
- LCP2 | c.1141T>G p.F381V | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- LHX4 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 127/409 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRFN5 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP1B | c.7474A>G p.R2492G | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRK2 | c.3552A>C p.K1184N | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEA11 | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 165/511 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAGEC1 | c.3249A>C p.K1083N | Missense Mutation (SNP) | VAF 145/506 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MALRD1 | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MAP2K4 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2
- MAP6 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- MLLT10 | c.1070C>A p.P357Q | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MYT1L | c.2279A>C p.N760T | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- NCAM1 | c.1339T>G p.S447A (on ENST00000316851 / NM_181351.5; = p.S437A on NM_000615.7) | Missense Mutation (SNP) | VAF 143/455 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NCAPD3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NCOR1 | c.5791A>G p.N1931D | Missense Mutation (SNP) | VAF 133/279 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- NCS1 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by mutect2, varscan2
- ONECUT3 | c.835_851del p.S279Gfs*191 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- OR2T33 | c.961T>G p.*321Gext*5 | Nonstop Mutation (SNP) | VAF 50/143 reads (35%) | called by muse, varscan2
- OR5M10 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 118/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR6C65 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.027); called by muse, mutect2
- OR9H1P | c.475del p.T159Pfs*2 | Frame Shift Del (DEL) | VAF 84/403 reads (21%) | called by mutect2, pindel, varscan2
- OSBPL6 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OSTN | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OTOG | c.2348C>G p.S783C | Missense Mutation (SNP) | VAF 123/233 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PCDH10 | c.2298_2299del p.G767Ffs*31 | Frame Shift Del (DEL) | VAF 154/508 reads (30%) | called by pindel, varscan2
- PCLO | c.13764G>T p.L4588= | Splice Region (SNP) | VAF 127/421 reads (30%) | called by muse, mutect2, varscan2
- PCLO | c.10987A>G p.K3663E | Missense Mutation (SNP) | VAF 85/518 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PCSK4 | c.404del p.P135Qfs*3 | Frame Shift Del (DEL) | VAF 97/215 reads (45%) | called by mutect2, pindel*, varscan2
- PEX14 | c.224del p.D75Vfs*81 | Frame Shift Del (DEL) | VAF 111/292 reads (38%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.785dup p.S263Qfs*2 | Frame Shift Ins (INS) | VAF 226/868 reads (26%) | called by mutect2, pindel, varscan2
- PJVK | c.895T>G p.L299V | Missense Mutation (SNP) | VAF 186/297 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PLEC | c.13388C>T p.T4463I (on ENST00000322810 / NM_201380.4; = p.T4353I on NM_000445.5) | Missense Mutation (SNP) | VAF 205/561 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PLXNB2 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 214/402 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- POLA2 | c.371_377del p.A124Vfs*7 | Frame Shift Del (DEL) | VAF 90/310 reads (29%) | called by mutect2, pindel, varscan2
- POTEM | c.1184A>C p.N395T | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R9A | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 66/495 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PREX2 | c.1541A>C p.N514T | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RAB29 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- RBMS2 | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 126/214 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RGL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 123/232 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGPD3 | c.1655T>G p.L552W | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SAGE1 | c.1127C>A p.A376D | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMD9 | c.1700T>G p.L567R | Missense Mutation (SNP) | VAF 81/525 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SART3 | c.1747G>A p.A583T (on ENST00000228284; = p.A565T on NM_014706.4) | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SCN9A | c.3173A>C p.K1058T (on ENST00000303354; = p.K1047T on NM_002977.3) | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SETBP1 | c.3820A>G p.R1274G | Missense Mutation (SNP) | VAF 136/277 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SH3YL1 | c.112+1G>A p.X38_splice | Splice Site (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- SLC23A3 | c.1304T>G p.V435G (on ENST00000409878 / NM_001144889.2; = p.V318G on NM_144712.5) | Missense Mutation (SNP) | VAF 213/312 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SLC39A12 | c.1582A>G p.T528A (on ENST00000377369 / NM_001145195.2; = p.T491A on NM_152725.3) | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC8A3 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 251/379 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.4300C>A p.P1434T | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK5 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTG2 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 205/403 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNM | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 130/1009 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAF11L12 | c.583dup p.I195Nfs*? | Frame Shift Ins (INS) | VAF 74/260 reads (28%) | called by mutect2, varscan2
- TG | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 164/1698 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.212); called by muse, mutect2
- TG | c.3330A>C p.E1110D | Missense Mutation (SNP) | VAF 90/1082 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2
- TLR7 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 176/386 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM33 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TRIM9 | c.1972T>G p.L658V | Missense Mutation (SNP) | VAF 256/403 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.344); called by muse, mutect2
- TRPC6 | c.2352T>G p.I784M | Missense Mutation (SNP) | VAF 120/401 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TSHZ3 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 130/454 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- UBASH3B | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 283/582 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- UTP20 | c.540T>G p.H180Q | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2
- VPS13B | c.7581C>G p.F2527L | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDPCP | c.639C>G p.F213L | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZFP42 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 112/341 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF415 | c.956A>G p.Q319R | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF526 | c.1379A>T p.H460L | Missense Mutation (SNP) | VAF 172/557 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF569 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF641 | c.526T>G p.L176V | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF675 | c.232T>G p.C78G | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF701 | c.404T>G p.V135G (on ENST00000301093; = p.V69G on NM_018260.3) | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF800 | c.1177dup p.R393Kfs*6 | Frame Shift Ins (INS) | VAF 167/389 reads (43%) | called by mutect2, pindel, varscan2
- ZNF836 | c.1572A>C p.K524N | Missense Mutation (SNP) | VAF 112/412 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA13 | c.10146T>C p.F3382= | Silent (SNP) | VAF 89/468 reads (19%) | catalogued as rs765322212; called by muse, mutect2, varscan2
- ADRA1B | c.1128C>A p.R376= | Silent (SNP) | VAF 119/402 reads (30%) | catalogued as rs1561612939, COSV100140557; called by muse, mutect2, varscan2
- ANKRD36B | c.375C>T p.Y125= | Silent (SNP) | VAF 106/374 reads (28%) | catalogued as rs774163578; called by muse, varscan2
- AQP10 | c.870T>C p.T290= | Silent (SNP) | VAF 97/336 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.945C>T p.D315= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as rs770219638, COSV60603351, COSV60607161; called by muse, varscan2
- ARHGAP31 | c.648T>C p.F216= | Silent (SNP) | VAF 121/343 reads (35%) | called by muse, mutect2, varscan2
- BCHE | c.1287T>C p.P429= | Silent (SNP) | VAF 220/383 reads (57%) | called by muse, mutect2, varscan2
- C2orf81 | c.1275C>G p.L425= | Silent (SNP) | VAF 32/644 reads (5%) | called by muse, mutect2
- C5orf49 | c.417C>T p.P139= | Silent (SNP) | VAF 80/406 reads (20%) | catalogued as rs371256350; called by muse, varscan2
- CACNA1G | c.3678C>T p.D1226= | Silent (SNP) | VAF 83/332 reads (25%) | catalogued as rs752544601; called by muse, mutect2, varscan2
- CAMK4 | c.1020A>G p.G340= | Silent (SNP) | VAF 96/303 reads (32%) | called by muse, mutect2, varscan2
- CHGB | c.945C>T p.N315= | Silent (SNP) | VAF 271/634 reads (43%) | catalogued as rs779863087; called by muse, mutect2, varscan2
- CNNM1 | c.336C>G p.P112= | Silent (SNP) | VAF 209/430 reads (49%) | called by muse, mutect2, varscan2
- CNTN5 | c.2343C>T p.S781= | Silent (SNP) | VAF 60/246 reads (24%) | catalogued as rs202149564, COSV99676844; called by muse, mutect2, varscan2
- CNTN6 | c.1728C>T p.L576= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as COSV100611987, COSV63170502; called by muse, mutect2, varscan2
- COL10A1 | c.807T>A p.A269= | Silent (SNP) | VAF 123/377 reads (33%) | called by muse, mutect2, varscan2
- DENND4C | c.2232C>G p.L744= | Silent (SNP) | VAF 80/170 reads (47%) | called by muse, mutect2, varscan2
- DGKI | c.2055G>A p.R685= | Silent (SNP) | VAF 146/516 reads (28%) | catalogued as COSV55976986, COSV99932185; called by muse, mutect2, varscan2
- DHH | c.981G>A p.P327= | Silent (SNP) | VAF 287/710 reads (40%) | catalogued as rs1015602628; called by muse, mutect2, varscan2
- DMD | c.9654T>C p.L3218= | Silent (SNP) | VAF 99/175 reads (57%) | catalogued as CD071334; called by muse, mutect2, varscan2
- DNAH5 | c.9939C>A p.G3313= | Silent (SNP) | VAF 330/440 reads (75%) | called by muse, varscan2
- DNAH5 | c.4549A>C p.R1517= | Silent (SNP) | VAF 97/413 reads (23%) | called by muse, mutect2, varscan2
- DPPA4 | c.588T>G p.T196= | Silent (SNP) | VAF 124/393 reads (32%) | catalogued as COSV59509519; called by muse, mutect2, varscan2
- EXOC6B | c.861A>G p.Q287= | Silent (SNP) | VAF 163/383 reads (43%) | called by muse, mutect2, varscan2
- EZHIP | c.1485T>C p.A495= | Silent (SNP) | VAF 98/212 reads (46%) | called by muse, mutect2, varscan2
- FAM135B | c.3684C>T p.L1228= | Silent (SNP) | VAF 105/298 reads (35%) | catalogued as COSV52724924; called by muse, mutect2, varscan2
- FAM178B | c.339G>T p.P113= | Silent (SNP) | VAF 34/550 reads (6%) | called by muse, mutect2
- FBN3 | c.7737C>T p.C2579= | Silent (SNP) | VAF 138/264 reads (52%) | catalogued as rs767651414, COSV54460531; called by muse, mutect2, varscan2
- FBXW4 | c.1653C>T p.L551= | Silent (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- GAA | c.2157G>A p.A719= | Silent (SNP) | VAF 178/525 reads (34%) | catalogued as rs201523530; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- GALNT13 | c.762T>C p.T254= | Silent (SNP) | VAF 148/242 reads (61%) | catalogued as COSV101224183, COSV67224717, COSV67225652; called by muse, mutect2, varscan2
- GTF2E1 | c.939T>G p.A313= | Silent (SNP) | VAF 97/285 reads (34%) | called by muse, mutect2, varscan2
- HMCN1 | c.4779A>G p.Q1593= | Silent (SNP) | VAF 150/483 reads (31%) | called by muse, mutect2, varscan2
- IGHM | c.762C>T p.S254= | Silent (SNP) | VAF 148/302 reads (49%) | catalogued as rs1276984860; called by muse, varscan2
- IPCEF1 | c.837T>G p.S279= | Silent (SNP) | VAF 98/282 reads (35%) | called by muse, mutect2, varscan2
- IRAK1 | c.864C>T p.Y288= | Silent (SNP) | VAF 159/518 reads (31%) | catalogued as rs374510973, COSV100317752; called by muse, mutect2, varscan2
- KATNB1 | c.1581C>T p.S527= | Silent (SNP) | VAF 95/432 reads (22%) | catalogued as rs782356618, COSV65550481; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCND3 | c.1350C>A p.L450= | Silent (SNP) | VAF 110/238 reads (46%) | catalogued as COSV56174143; called by muse, mutect2, varscan2
- KCNS2 | c.78C>T p.F26= | Silent (SNP) | VAF 184/475 reads (39%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.633T>C p.P211= | Silent (SNP) | VAF 111/355 reads (31%) | called by muse, mutect2, varscan2
- KLHL38 | c.391T>C p.L131= | Silent (SNP) | VAF 131/1814 reads (7%) | catalogued as rs372636699; called by muse, mutect2
- KRT2 | c.825C>T p.R275= | Silent (SNP) | VAF 117/389 reads (30%) | called by muse, mutect2, varscan2
- KRT35 | c.166C>T p.L56= | Silent (SNP) | VAF 178/6457 reads (3%) | called by muse, mutect2
- KRTAP16-1 | c.222T>C p.C74= | Silent (SNP) | VAF 205/9285 reads (2%) | called by muse, mutect2
- LAMC2 | c.3084G>T p.L1028= | Silent (SNP) | VAF 76/282 reads (27%) | catalogued as COSV99917313; called by muse, mutect2, varscan2
- LMTK2 | c.2475G>A p.T825= | Silent (SNP) | VAF 156/598 reads (26%) | catalogued as rs763335623, COSV51993603; called by muse, mutect2
- LRATD2 | c.903G>A p.E301= | Silent (SNP) | VAF 156/1569 reads (10%) | catalogued as rs746320331; called by muse, mutect2
- LRP1B | c.576T>A p.S192= | Silent (SNP) | VAF 104/174 reads (60%) | catalogued as COSV67230122; called by muse, mutect2, varscan2
- LRP2 | c.7638G>A p.V2546= | Silent (SNP) | VAF 94/306 reads (31%) | catalogued as rs1299722831; called by muse, mutect2, varscan2
- LRRC4B | c.882C>T p.H294= | Silent (SNP) | VAF 183/541 reads (34%) | catalogued as rs1167226591, COSV65349545; called by muse, mutect2, varscan2
- MARK2 | c.93G>A p.K31= | Silent (SNP) | VAF 271/440 reads (62%) | called by muse, mutect2, varscan2
- MCOLN1 | c.1119C>T p.I373= | Silent (SNP) | VAF 130/268 reads (49%) | catalogued as rs765687408, COSV51179385; called by muse, mutect2, varscan2
- MUC22 | c.2100T>G p.T700= | Silent (SNP) | VAF 217/434 reads (50%) | catalogued as rs532002752; called by muse, mutect2, varscan2
- MUC4 | c.5535C>T p.I1845= | Silent (SNP) | VAF 159/1199 reads (13%) | catalogued as COSV100640129; called by muse, mutect2, varscan2
- MYF5 | c.762G>A p.V254= | Silent (SNP) | VAF 132/132 reads (100%) | called by muse, mutect2, varscan2
- MYOM2 | c.3406T>C p.L1136= | Silent (SNP) | VAF 139/2468 reads (6%) | catalogued as rs761840713; called by muse, mutect2
- NAPRT | c.1062C>A p.V354= | Silent (SNP) | VAF 40/695 reads (6%) | catalogued as COSV99434829; called by muse, mutect2
- NUP214 | c.3912C>T p.S1304= | Silent (SNP) | VAF 130/276 reads (47%) | catalogued as rs746592194; called by muse, mutect2, varscan2
- NYAP1 | c.157C>A p.R53= | Silent (SNP) | VAF 143/897 reads (16%) | catalogued as COSV55721082; called by muse, mutect2, varscan2
- OGFR | c.1785C>T p.A595= | Silent (SNP) | VAF 220/947 reads (23%) | catalogued as rs774934469; called by muse, mutect2, varscan2
- OR2D3 | c.162C>T p.T54= | Silent (SNP) | VAF 126/228 reads (55%) | catalogued as rs372928530; called by muse, mutect2, varscan2
- OR4A47 | c.258G>T p.G86= | Silent (SNP) | VAF 269/434 reads (62%) | called by muse, mutect2, varscan2
- OR5D16 | c.780C>T p.L260= | Silent (SNP) | VAF 88/403 reads (22%) | catalogued as rs777333437; called by muse, mutect2, varscan2
- OR8B2 | c.327C>A p.I109= | Silent (SNP) | VAF 114/460 reads (25%) | called by muse, mutect2, varscan2
- OVOL2 | c.471C>T p.N157= | Silent (SNP) | VAF 96/422 reads (23%) | catalogued as rs553869449; called by muse, varscan2
- PCK1 | c.298A>C p.R100= | Silent (SNP) | VAF 124/584 reads (21%) | catalogued as COSV60128112; called by muse, mutect2, varscan2
- PEG3 | c.2020A>C p.R674= | Silent (SNP) | VAF 130/446 reads (29%) | called by muse, mutect2, varscan2
- PEX26 | c.861C>T p.F287= | Silent (SNP) | VAF 163/334 reads (49%) | called by muse, mutect2, varscan2
- PLXDC2 | c.855C>T p.V285= | Silent (SNP) | VAF 97/291 reads (33%) | catalogued as rs927570708; called by muse, mutect2, varscan2
- PNPLA7 | c.2454C>T p.A818= | Silent (SNP) | VAF 147/701 reads (21%) | catalogued as rs143853424; called by muse, mutect2, varscan2
- PPP1R2B | c.84G>A p.S28= | Silent (SNP) | VAF 123/570 reads (22%) | catalogued as rs778681228, COSV70372913; called by muse, mutect2, varscan2
- PPRC1 | c.1875C>T p.L625= | Silent (SNP) | VAF 177/323 reads (55%) | catalogued as rs752249199; called by muse, mutect2, varscan2
- RAG1 | c.507G>A p.S169= | Silent (SNP) | VAF 126/286 reads (44%) | catalogued as COSV55027978, COSV55028142; called by muse, mutect2, varscan2
- RNGTT | c.1065T>C p.A355= | Silent (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- SAFB | c.525G>A p.P175= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as rs758696281, COSV52652537; called by muse, mutect2, varscan2
- SLC14A2 | c.840C>G p.P280= | Silent (SNP) | VAF 93/169 reads (55%) | called by muse, mutect2, varscan2
- SMPD3 | c.1116C>A p.T372= | Silent (SNP) | VAF 140/629 reads (22%) | called by muse, mutect2, varscan2
- SNAP25 | c.543C>A p.I181= | Silent (SNP) | VAF 52/437 reads (12%) | catalogued as COSV99655376; called by muse, mutect2, varscan2
- SOX18 | c.753C>T p.P251= | Silent (SNP) | VAF 163/857 reads (19%) | catalogued as rs978614980; called by muse, mutect2, varscan2
- SPEN | c.6249C>T p.S2083= | Silent (SNP) | VAF 107/233 reads (46%) | called by muse, mutect2, varscan2
- STARD13 | c.1035G>A p.T345= (on ENST00000336934 / NM_001243476.3; = p.T227= on NM_052851.3) | Silent (SNP) | VAF 175/340 reads (51%) | catalogued as rs768240114, COSV99716404; called by muse, mutect2, varscan2
- SYNE1 | c.10350A>G p.E3450= (on ENST00000367255 / NM_182961.4; = p.E3457= on NM_033071.3) | Silent (SNP) | VAF 137/393 reads (35%) | called by muse, mutect2, varscan2
- TENM4 | c.837T>C p.A279= | Silent (SNP) | VAF 130/402 reads (32%) | called by muse, mutect2, varscan2
- TENT4A | c.510C>T p.R170= | Silent (SNP) | VAF 266/1076 reads (25%) | called by muse, mutect2, varscan2
- TG | c.4065T>G p.G1355= | Silent (SNP) | VAF 166/1934 reads (9%) | called by muse, mutect2
- TMEM171 | c.963T>G p.P321= | Silent (SNP) | VAF 51/178 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.14235T>C p.S4745= (on ENST00000591111; = p.S3818= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/334 reads (32%) | called by muse, mutect2, varscan2
- VPS13D | c.10128G>A p.L3376= | Silent (SNP) | VAF 83/176 reads (47%) | called by muse, mutect2, varscan2
- VWA3B | c.2232T>G p.T744= | Silent (SNP) | VAF 277/430 reads (64%) | called by muse, mutect2, varscan2
- WDR64 | c.2091G>A p.L697= | Silent (SNP) | VAF 66/255 reads (26%) | called by muse, mutect2, varscan2
- ZC3H4 | c.3132A>G p.E1044= | Silent (SNP) | VAF 213/587 reads (36%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.360C>T p.S120= | Silent (SNP) | VAF 84/240 reads (35%) | catalogued as COSV101043364; called by muse, mutect2, varscan2
- ZNF578 | c.285T>C p.S95= | Silent (SNP) | VAF 75/201 reads (37%) | catalogued as COSV101405083; called by muse, mutect2, varscan2
- AC092070.2 | n.1619T>G | RNA (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-1277G>A | Intron (SNP) | VAF 306/307 reads (100%) | catalogued as rs750491023, COSV66930126; called by muse, mutect2, varscan2
- CLEC20A | c.928+1726C>T | Intron (SNP) | VAF 63/500 reads (13%) | called by muse, mutect2, varscan2
- GPSM1 | c.1207+43C>T | Intron (SNP) | VAF 181/1350 reads (13%) | catalogued as rs950065771; called by muse, varscan2
- HBS1L | c.430+2096C>G | Intron (SNP) | VAF 65/184 reads (35%) | called by muse, mutect2, varscan2
- SLC12A5 | c.122-5571C>T | Intron (SNP) | VAF 150/717 reads (21%) | called by muse, mutect2, varscan2
- SPAG11B | c.*116G>C | 3'UTR (SNP) | VAF 121/3296 reads (4%) | called by muse, mutect2
- TTN | c.35375-1417A>G | Intron (SNP) | VAF 160/261 reads (61%) | called by muse, mutect2, varscan2
- TTN | c.34354+1002A>C | Intron (SNP) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- UNC13B | c.761+7048A>G | Intron (SNP) | VAF 81/180 reads (45%) | called by muse, mutect2, varscan2
- ZNF135 | chr19:58059264 G>A | 5'Flank (SNP) | VAF 131/471 reads (28%) | catalogued as rs868426067; called by muse, mutect2, varscan2
- ZNF83 | c.-67A>T | 5'UTR (SNP) | VAF 170/279 reads (61%) | called by muse, mutect2, varscan2
